Somatic mutation profile of tumor specimen TCGA-42-2587-01A (aliquot TCGA-42-2587-01A-01D-1526-09) from TCGA case TCGA-42-2587, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 75.3 years (27,510 days).
Specimen TCGA-42-2587-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e2a06ae-2a16-4a5f-b28e-6eff717f84fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-42-2587-10A (Blood Derived Normal), aliquot TCGA-42-2587-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1605156e-6dae-4ef8-b567-9722fa3d974e

The open-access MAF lists 157 somatic variants for this specimen: 126 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 30, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 2, 5'UTR 1, In Frame Del 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 108/208 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AAMP | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 73/284 reads (26%) | catalogued as COSV50309603; called by muse, mutect2, varscan2
- ABHD14B | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59986392; called by muse, mutect2, varscan2
- AFF4 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV54799546; called by muse, mutect2, varscan2
- AKAP3 | c.1635G>T p.R545S | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV57420265; called by muse, mutect2, varscan2
- AKAP9 | c.7471G>T p.V2491L (on ENST00000359028; = p.V2467L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV62357214; called by muse, mutect2, varscan2
- ANKRD1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs1293523344, COSV65467209; called by muse, mutect2, varscan2
- APBB1IP | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 111/386 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63304494; called by muse, mutect2, varscan2
- ARHGAP32 | c.4637G>A p.G1546E (on ENST00000310343 / NM_001378025.1; = p.G1197E on NM_014715.4) | Missense Mutation (SNP) | VAF 78/494 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.368); catalogued as COSV100089192; called by muse, varscan2
- ASB13 | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 148/536 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63092122; called by muse, mutect2, varscan2
- ATG16L2 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 53/558 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV58362859; called by muse, mutect2, varscan2
- BCL9L | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.769); catalogued as COSV58307968, COSV58320129; called by muse, mutect2, varscan2
- C9orf131 | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 126/241 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100397949, COSV56613995; called by muse, mutect2, varscan2
- CAPN12 | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV99400706; called by muse, mutect2
- CD36 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs958616073, COSV59219385; called by muse, mutect2, varscan2
- CDC73 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV66468382, COSV66470228; called by muse, mutect2, varscan2
- CDH5 | c.2142C>G p.D714E | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.315); catalogued as rs772939635, COSV58518209, COSV58519804; called by muse, mutect2, varscan2
- CEACAM19 | c.780A>G p.I260M | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV62552293; called by muse, mutect2, varscan2
- CHRM2 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 64/285 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV57783793; called by muse, mutect2, varscan2
- CHSY1 | c.1389G>C p.M463I | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV54255831; called by muse, mutect2, varscan2
- CLCN1 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 140/672 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563078716, CM1313401, COSV58374185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN6 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 215/707 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100411778, COSV56742917; called by muse, mutect2, varscan2
- CRYBA1 | c.213C>T p.G71= | Splice Region (SNP) | VAF 34/216 reads (16%) | catalogued as rs761047403, CM1410348, COSV56601510; called by muse, mutect2, varscan2
- CSMD2 | c.6868C>G p.P2290A | Missense Mutation (SNP) | VAF 165/359 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV53958341, COSV99596357; called by muse, mutect2, varscan2
- CXCL12 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as COSV59109192; called by muse, mutect2, varscan2
- CYP1A2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376179316; called by muse, mutect2, varscan2
- DAP3 | c.876C>G p.N292K | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs1330963248, COSV58022721; called by muse, mutect2, varscan2
- DDX53 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100029090; called by muse, mutect2
- DGKI | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 233/548 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs200049424, COSV55973626; called by muse, mutect2, varscan2
- DHRSX | c.750C>G p.H250Q | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58138541; called by muse, mutect2, varscan2
- DNAH8 | c.10459G>T p.D3487Y | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV59478252; called by muse, mutect2, varscan2
- E2F4 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as rs1389030539, COSV58877081; called by muse, mutect2, varscan2
- ESR1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 235/410 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV52782296, COSV52802623; called by muse, mutect2, varscan2
- FAM117A | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 12/413 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as COSV99544565, COSV99545168; called by muse, mutect2
- FBN2 | c.2518G>A p.G840R | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52543574; called by muse, mutect2, varscan2
- FCN2 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52478629; called by muse, mutect2, varscan2
- FCRL3 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63844724; called by muse, mutect2, varscan2
- FCRL4 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54860291, COSV54860980; called by muse, mutect2, varscan2
- GEMIN7 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV54320739; called by muse, mutect2, varscan2
- GRIA2 | c.1463T>A p.L488H | Missense Mutation (SNP) | VAF 163/353 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52387936, COSV52404780; called by muse, mutect2, varscan2
- HELQ | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV55027759, COSV55028586; called by muse, mutect2, varscan2
- HENMT1 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 91/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64230746; called by muse, mutect2, varscan2
- HPD | c.928G>C p.V310L | Missense Mutation (SNP) | VAF 209/465 reads (45%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.868); catalogued as COSV56643656; called by muse, mutect2, varscan2
- IGDCC3 | c.1406A>G p.E469G | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV60080084; called by muse, mutect2, varscan2
- INTS12 | c.425A>T p.D142V | Missense Mutation (SNP) | VAF 165/356 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV60863530; called by muse, mutect2, varscan2
- ITGAL | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV63324221; called by muse, varscan2
- ITIH5 | c.341G>C p.R114T | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV56914037, COSV56917802; called by muse, mutect2, varscan2
- KCNT1 | c.256T>C p.F86L (on ENST00000488444; = p.F105L on NM_020822.3) | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV53710008; called by muse, mutect2, varscan2
- KIF27 | c.2180G>C p.R727T | Missense Mutation (SNP) | VAF 85/322 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs543373060, COSV52829092, COSV52830986; called by muse, mutect2, varscan2
- KLC2 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs778882287, COSV57584171; called by muse, mutect2, varscan2
- KLF16 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1296884555, COSV51737218; called by muse, mutect2, varscan2
- KRT83 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.377); catalogued as rs140443749, COSV53338480; ClinVar: uncertain significance; called by muse, mutect2
- LAMA3 | c.7600G>A p.E2534K (on ENST00000313654 / NM_198129.4; = p.E925K on NM_000227.6) | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV52542905; called by muse, mutect2, varscan2
- LGALS3BP | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV53166048; called by muse, mutect2, varscan2
- MAGEB6 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV66873015; called by muse, mutect2, varscan2
- MAP4K3 | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV55718017; called by muse, mutect2, varscan2
- MASP1 | c.800C>G p.P267R | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV51463664; called by muse, mutect2, varscan2
- MCM8 | c.851T>G p.V284G | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV54518950; called by muse, mutect2, varscan2
- MDH1B | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV65590438, COSV65591643; called by muse, mutect2, varscan2
- MFSD11 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 94/203 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs749609248, COSV100334051, COSV60622332; called by muse, mutect2, varscan2
- MTNR1B | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1451347407, COSV57068780; called by muse, mutect2, varscan2
- MYH4 | c.428A>T p.Y143F | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV55125645; called by muse, mutect2, varscan2
- MYH6 | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 179/512 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV62454234; called by muse, mutect2, varscan2
- MYL7 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV56267432, COSV56268968, COSV56269180; called by muse, mutect2, varscan2
- MYOC | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50678366; called by muse, mutect2, varscan2
- NAMPT | c.441G>C p.W147C | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV55996599; called by muse, mutect2, varscan2
- NOXO1 | c.353C>G p.P118R (on ENST00000397280 / NM_172168.3; = p.P112R on NM_144603.4) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.406); catalogued as rs1008445243, COSV50191879, COSV50191900; called by muse, mutect2, varscan2
- NSMCE3 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs949806571, COSV54286946; called by muse, mutect2, varscan2
- NYX | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV61181686; called by muse, mutect2, varscan2
- OR2T6 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 87/493 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749214490, COSV63217019; called by muse, mutect2, varscan2
- OR4F6 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 151/583 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV61027575; called by muse, mutect2, varscan2
- OR5AC2 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs1359004831, COSV62280127; called by muse, mutect2, varscan2
- OR8A1 | c.19T>G p.S7A | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV52510317; called by muse, mutect2, varscan2
- OR9G4 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100265265; called by muse, mutect2, varscan2
- PAN2 | c.3002A>T p.K1001I (on ENST00000425394 / NM_001127460.3; = p.K997I on NM_014871.5) | Missense Mutation (SNP) | VAF 158/479 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV56265110; called by muse, mutect2, varscan2
- PCDHB11 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV53383464; called by muse, mutect2, varscan2
- PDK1 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 94/502 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as rs764312711, COSV56376986; called by muse, mutect2, varscan2
- PFKM | c.1377G>T p.W459C | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56660166; called by muse, mutect2, varscan2
- PLCB3 | c.3601G>T p.D1201Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54192134; called by mutect2, varscan2
- POU2AF1 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 59/486 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV67577739; called by muse, mutect2, varscan2
- PPARG | c.957G>C p.E319D (on ENST00000287820 / NM_015869.5; = p.E289D on NM_005037.7) | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as COSV99826769; called by muse, mutect2
- PPIP5K2 | c.488-1G>A p.X163_splice | Splice Site (SNP) | VAF 12/111 reads (11%) | catalogued as COSV58609514; called by muse, mutect2, varscan2
- PREX1 | c.3561A>T p.R1187S | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.65); catalogued as COSV100906789; called by muse, mutect2
- PRKAG1 | c.495C>G p.Y165* | Nonsense Mutation (SNP) | VAF 143/488 reads (29%) | catalogued as COSV60294644; called by muse, mutect2, varscan2
- RARS2 | c.601C>A p.H201N | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65762730; called by muse, mutect2, varscan2
- RASGRF1 | c.1836G>T p.R612S | Missense Mutation (SNP) | VAF 311/744 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV69183013; called by muse, mutect2, varscan2
- RBL2 | c.2740C>T p.R914C | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV50882855; called by muse, mutect2, varscan2
- RELN | c.664T>G p.C222G | Missense Mutation (SNP) | VAF 43/466 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100634857; called by muse, mutect2
- RNPEP | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 205/650 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV55243950; called by muse, mutect2, varscan2
- ROBO4 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs1339789671, COSV60627801; called by muse, mutect2, varscan2
- SEC23IP | c.268A>C p.S90R | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV64832994; called by muse, mutect2, varscan2
- SIK3 | c.386A>C p.E129A (on ENST00000445177 / NM_001366686.2; = p.E135A on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/596 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV52622735; called by muse, mutect2, varscan2
- SLC3A1 | c.1329G>C p.W443C | Missense Mutation (SNP) | VAF 86/455 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270635310, COSV99577614; called by muse, mutect2
- SLC6A1 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55118617; called by muse, mutect2, varscan2
- STAT4 | c.1690C>A p.H564N | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV61832147; called by muse, mutect2, varscan2
- STUB1 | c.194A>T p.N65I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM149564, COSV50204071; called by muse, mutect2, varscan2
- SUGP1 | c.702C>A p.Y234* | Nonsense Mutation (SNP) | VAF 63/503 reads (13%) | catalogued as COSV55923785; called by muse, mutect2, varscan2
- SUPT6H | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100112467, COSV58931283; called by muse, mutect2, varscan2
- SVIL | c.4454G>A p.G1485E (on ENST00000355867 / NM_021738.3; = p.G1059E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63447872; called by muse, mutect2, varscan2
- SYNE2 | c.13141G>C p.D4381H | Missense Mutation (SNP) | VAF 8/300 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100648447; called by muse, mutect2
- SYNGAP1 | c.549T>G p.H183Q | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV53386407; called by muse, mutect2, varscan2
- TMEM38B | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65951341; called by muse, mutect2, varscan2
- TPH2 | c.694C>G p.P232A | Missense Mutation (SNP) | VAF 167/559 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV61591462, COSV61593532, COSV61594165; called by muse, mutect2, varscan2
- TRPC1 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99859304; called by muse, mutect2
- TRPV3 | c.403T>A p.L135M | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56788796; called by muse, mutect2, varscan2
- UGT1A1 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV59397609; called by muse, mutect2, varscan2
- UPF3A | c.828G>C p.E276D | Missense Mutation (SNP) | VAF 97/155 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV60896144; called by muse, mutect2, varscan2
- USH2A | c.11593G>T p.A3865S | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as COSV100242149; called by muse, mutect2
- VPS13B | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100663471; called by muse, mutect2
- WDR47 | c.2101G>T p.D701Y (on ENST00000369962 / NM_001142551.2; = p.D702Y on NM_014969.5) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV63059713; called by muse, mutect2, varscan2
- WFS1 | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs751466013, COSV56991519; called by muse, mutect2, varscan2
- WHRN | c.2479G>T p.G827C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54334663; called by muse, mutect2, varscan2
- WNK2 | c.5217G>T p.E1739D (on ENST00000297954 / NM_001282394.1; = p.E1702D on NM_006648.3) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.422); catalogued as COSV52959159; called by muse, mutect2, varscan2
- XYLT1 | c.1922T>G p.I641S | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.14); catalogued as COSV99763235; called by muse, mutect2, varscan2
- ZNF483 | c.1253A>T p.K418I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100493117; called by muse, mutect2
- ZNF816 | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 89/259 reads (34%) | catalogued as rs750527469, COSV54412424; called by muse, mutect2, varscan2
- CCNQ | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 18/616 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2
- CLCA2 | c.186+5_186+41del p.X62_splice | Splice Site (DEL) | VAF 46/178 reads (26%) | called by mutect2, pindel
- CLCN2 | c.2573_2607del p.R858Hfs*2 | Frame Shift Del (DEL) | VAF 22/161 reads (14%) | called by mutect2, pindel
- DNAJB13 | c.563_583del p.W188_T195delinsS | In Frame Del (DEL) | VAF 106/824 reads (13%) | called by mutect2, pindel
- FAH | c.215_234del p.G72Efs*21 | Frame Shift Del (DEL) | VAF 544/865 reads (63%) | called by mutect2, pindel, varscan2
- FBXW9 | c.1163_1165dup p.L388dup (on ENST00000587955; = p.L368dup on NM_032301.3) | In Frame Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- GABRA3 | c.362_371del p.T121Mfs*4 | Frame Shift Del (DEL) | VAF 103/624 reads (17%) | called by mutect2, pindel, varscan2
- MKNK1 | c.852_880del p.S284Rfs*21 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel
- MORC2 | c.2056_2078del p.S686Afs*42 (on ENST00000397641 / NM_001303256.3; = p.S624Afs*42 on NM_014941.3) | Frame Shift Del (DEL) | VAF 21/170 reads (12%) | called by mutect2, pindel
- RB1 | c.1268del p.G423Dfs*34 | Frame Shift Del (DEL) | VAF 82/182 reads (45%) | called by mutect2, pindel, varscan2
- ANGPTL1 | c.159C>T p.F53= | Silent (SNP) | VAF 147/508 reads (29%) | catalogued as COSV52368115; called by muse, mutect2, varscan2
- ANKRD34A | c.780A>T p.P260= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV60161981; called by muse, mutect2, varscan2
- ARHGAP32 | c.4638A>C p.G1546= (on ENST00000310343 / NM_001378025.1; = p.G1197= on NM_014715.4) | Silent (SNP) | VAF 84/494 reads (17%) | catalogued as COSV100089188; called by muse, varscan2
- C20orf141 | c.276T>A p.T92= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as COSV63028620; called by muse, mutect2, varscan2
- CDYL2 | c.894G>A p.L298= | Silent (SNP) | VAF 65/122 reads (53%) | catalogued as COSV73654894, COSV73655164; called by muse, mutect2, varscan2
- CPNE7 | c.198G>C p.R66= | Silent (SNP) | VAF 123/276 reads (45%) | catalogued as COSV52016375; called by muse, mutect2, varscan2
- FGFR4 | c.333G>A p.Q111= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52809471; called by muse, mutect2, varscan2
- GCM2 | c.609T>C p.G203= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV65275278; called by muse, mutect2, varscan2
- GJA10 | c.1071A>C p.S357= | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as COSV65356174; called by muse, mutect2, varscan2
- GPER1 | c.1047C>T p.N349= | Silent (SNP) | VAF 128/553 reads (23%) | catalogued as COSV52470596; called by muse, mutect2, varscan2
- H4C8 | c.141T>C p.I47= | Silent (SNP) | VAF 164/409 reads (40%) | catalogued as COSV99175513; called by muse, mutect2
- IFNL3 | c.426G>A p.T142= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs769150907, COSV101308027; called by muse, mutect2, varscan2
- INPPL1 | c.2634C>A p.R878= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as COSV99996621; called by muse, mutect2, varscan2
- KCNH4 | c.177G>A p.E59= | Silent (SNP) | VAF 55/93 reads (59%) | catalogued as rs755083253, COSV52920849; called by muse, mutect2, varscan2
- KLHDC3 | c.1131C>T p.I377= | Silent (SNP) | VAF 100/328 reads (30%) | catalogued as rs143460878, COSV55064152; called by muse, mutect2, varscan2
- KRTAP13-1 | c.114T>G p.T38= | Silent (SNP) | VAF 132/297 reads (44%) | catalogued as COSV100819922; called by muse, mutect2
- LRP2 | c.7290T>C p.S2430= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV55572433; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1680G>A p.P560= (on ENST00000259318 / NM_001136562.3; = p.P791= on NM_007203.5) | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as rs769186624, COSV99395702; called by muse, mutect2
- PATJ | c.1557C>G p.V519= | Silent (SNP) | VAF 74/206 reads (36%) | catalogued as COSV57171421; called by muse, mutect2, varscan2
- POLD3 | c.6G>A p.A2= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as COSV55245739; called by muse, mutect2, varscan2
- PPBP | c.111C>G p.T37= | Silent (SNP) | VAF 106/367 reads (29%) | catalogued as COSV56020214; called by muse, mutect2, varscan2
- PRSS37 | c.543G>A p.V181= | Silent (SNP) | VAF 77/333 reads (23%) | catalogued as COSV63340113; called by muse, mutect2, varscan2
- RALGDS | c.1278G>A p.L426= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as rs376963822; called by muse, mutect2, varscan2
- RYR1 | c.4377C>T p.H1459= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs772882086, COSV62097548; called by muse, mutect2, varscan2
- SLF1 | c.3081A>G p.E1027= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs769702094, COSV54373321; called by muse, mutect2, varscan2
- SORL1 | c.2640T>C p.A880= | Silent (SNP) | VAF 190/791 reads (24%) | catalogued as COSV52762004; called by muse, mutect2, varscan2
- TFR2 | c.2067G>A p.R689= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV56156332; called by muse, mutect2, varscan2
- TMTC3 | c.1794T>C p.D598= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV57126220; called by muse, mutect2, varscan2
- TP53I11 | c.493C>T p.L165= | Silent (SNP) | VAF 96/279 reads (34%) | catalogued as COSV57534124; called by muse, mutect2, varscan2
- XYLT1 | c.1923C>A p.I641= | Silent (SNP) | VAF 30/293 reads (10%) | catalogued as COSV99763233; called by muse, mutect2, varscan2
- C1orf35 | c.-1C>T | 5'UTR (SNP) | VAF 15/76 reads (20%) | catalogued as rs891275618, COSV99683338; called by muse, mutect2, varscan2
